Somatic mutation profile of tumor specimen TCGA-RD-A8MV-01A (aliquot TCGA-RD-A8MV-01A-11D-A364-08) from TCGA case TCGA-RD-A8MV, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.9 years (20,771 days).
Specimen TCGA-RD-A8MV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89116bd3-1aba-4b8a-8aff-2916e5cdd87b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RD-A8MV-10A (Blood Derived Normal), aliquot TCGA-RD-A8MV-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13eb5bfc-2078-4fdc-97f5-90dc28a99fc9

The open-access MAF lists 69 somatic variants for this specimen: 60 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 48, Silent 9, Nonsense Mutation 6, Frame Shift Del 4, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH1A3 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60902185; called by muse, mutect2, varscan2
- ANK3 | c.9738T>A p.N3246K | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1175435990, COSV99780920; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7084C>T p.R2362* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99783811; called by muse, mutect2, varscan2
- ARHGAP20 | c.2329A>G p.T777A | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99504617; called by muse, mutect2, varscan2
- BCL3 | c.372C>A p.D124E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.883); catalogued as COSV99378226; called by muse, mutect2, varscan2
- BICDL1 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1235027770, COSV99985901; called by muse, mutect2, varscan2
- CCDC88B | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199674677, COSV100105631; called by muse, mutect2, varscan2
- CYP26A1 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs927104767, COSV99814839; called by muse, mutect2, varscan2
- DSC3 | c.1522T>C p.Y508H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1262230309, COSV100844642; called by muse, mutect2, varscan2
- DSPP | c.207A>C p.Q69H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV56807373, COSV99217614; called by muse, mutect2
- EGR2 | c.956C>A p.P319H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1205570865, COSV99654207; called by muse, mutect2, varscan2
- EVC2 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100186339; called by muse, mutect2
- FAM107B | c.34C>T p.P12S (on ENST00000378458 / NM_001320737.1; = p.P187S on NM_031453.3) | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as COSV99474144; called by muse, mutect2, varscan2
- FLNC | c.4109G>A p.R1370Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs761881020, CM1512372, COSV57965666; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXP2 | c.584A>G p.K195R | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as COSV100647064; called by muse, mutect2
- HMCN1 | c.11531T>G p.L3844R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99631942; called by muse, mutect2, varscan2
- HOXD4 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754784160, COSV60461109; called by mutect2, varscan2
- IMPG2 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV99515949; called by muse, mutect2, varscan2
- ITGAD | c.2020T>G p.F674V | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV101210526; called by muse, mutect2, varscan2
- ITGAX | c.1733C>G p.S578C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV51644798, COSV99191881; called by muse, mutect2, varscan2
- KCNK5 | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV63988877; called by muse, mutect2
- KCNMB2 | c.453T>G p.N151K | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV64201510; called by muse, mutect2, varscan2
- KHDRBS2 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1458073424, COSV55484902; called by muse, mutect2
- KMT2B | c.5590C>T p.R1864* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as COSV55856587; called by muse, mutect2
- LRP1 | c.6208G>A p.D2070N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs965146489, COSV54502633; called by muse, mutect2, varscan2
- LRP2 | c.10651C>T p.R3551C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1188450012, COSV55567967; called by muse, mutect2, varscan2
- LYPD3 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV99746826; called by mutect2, varscan2
- MAEL | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 9/123 reads (7%) | catalogued as COSV63112319; called by muse, mutect2
- MED31 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1235320538, COSV51514074, COSV99854589; called by muse, mutect2, varscan2
- MNDA | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs201766714; called by muse, mutect2, varscan2
- MPPED1 | c.176C>A p.T59N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.545); catalogued as rs1393633966, COSV100501283; called by muse, mutect2, varscan2
- MTOR | c.2743G>T p.V915F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100816441; called by muse, mutect2, varscan2
- NLGN1 | c.1591A>C p.N531H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100849641, COSV64341962; called by muse, mutect2, varscan2
- NNMT | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.039); catalogued as rs375954126, COSV55473798; called by muse, mutect2, varscan2
- NPAP1 | c.1900A>C p.S634R | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV61508397, COSV61512207, COSV99051844; called by muse, mutect2
- OLFML2B | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756084192, COSV99038674, COSV99668646; called by muse, mutect2, varscan2
- OR4A15 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs762801581, COSV100124218; called by muse, mutect2, varscan2
- OR52N4 | c.788C>A p.S263Y | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV100421708, COSV57891226; called by muse, mutect2, varscan2
- PCDHGA6 | c.1371C>A p.Y457* | Nonsense Mutation (SNP) | VAF 8/107 reads (7%) | catalogued as COSV99541958, COSV99549379; called by muse, mutect2
- PDZRN4 | c.937C>T p.R313* (on ENST00000402685 / NM_001164595.2; = p.R55* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as rs1399342728, COSV54215278; called by muse, mutect2, varscan2
- PRR5L | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as rs757260286, COSV100287195, COSV100287462; called by muse, mutect2, varscan2
- RAB19 | c.227A>G p.Q76R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs367625241; called by muse, mutect2, varscan2
- RBM48 | c.731T>C p.L244S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV99720286; called by muse, mutect2, varscan2
- RCN2 | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV100312804; called by muse, mutect2, varscan2
- RIPK2 | c.577A>C p.M193L | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as COSV99610005; called by muse, mutect2, varscan2
- SH2D4B | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100214036; called by muse, mutect2, varscan2
- SLITRK1 | c.494T>G p.L165R | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV101000006; called by muse, mutect2, varscan2
- TEX30 | c.644G>C p.W215S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101052046; called by muse, varscan2
- THBS4 | c.2512G>A p.A838T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV100644351; called by muse, mutect2, varscan2
- USP54 | c.4090C>T p.H1364Y | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100357484; called by muse, mutect2
- ZDBF2 | c.4577T>C p.V1526A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV100985123; called by muse, mutect2, varscan2
- ZNF112 | c.913C>A p.Q305K (on ENST00000337401 / NM_001083335.2; = p.Q299K on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100496017; called by muse, mutect2, varscan2
- ZNF534 | c.117G>T p.E39D | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99989937, COSV99990157; called by muse, mutect2, varscan2
- AOC2 | c.993del p.F331Lfs*11 | Frame Shift Del (DEL) | VAF 12/103 reads (12%) | called by mutect2, pindel, varscan2
- ATM | c.1026dup p.E343Rfs*5 | Frame Shift Ins (INS) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- IRF2 | c.455del p.S152Mfs*10 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- OCRL | c.436del p.S146Qfs*13 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | called by mutect2, pindel
- OXSM | c.1163del p.G388Efs*13 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | called by mutect2, pindel, varscan2
- PGC | c.968_970del p.I323del | In Frame Del (DEL) | VAF 7/30 reads (23%) | called by pindel, varscan2
- TRAV1-2 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AGBL1 | c.2295G>A p.T765= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs765274157, COSV66853426; called by muse, mutect2, varscan2
- APOB | c.8865T>G p.T2955= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV99266560; called by muse, mutect2, varscan2
- CDR1 | c.732G>T p.L244= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100983431; called by muse, mutect2, varscan2
- FAM78B | c.378C>A p.G126= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100597678; called by muse, mutect2, varscan2
- GAB4 | c.129C>T p.S43= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1245488457, COSV68753950; called by muse, mutect2, varscan2
- LHFPL5 | c.171G>A p.P57= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as rs898563542, COSV64177058, COSV64178691; called by muse, mutect2
- PCDHGB3 | c.1344C>T p.N448= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV54069227; called by muse, mutect2, varscan2
- PTCHD3 | c.153G>A p.P51= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs1386975242, COSV71256764, COSV71257170; called by muse, mutect2, varscan2
- USF3 | c.5826C>T p.N1942= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as rs899751953, COSV100325513; called by muse, mutect2
